Gene-level copy-number profile of tumor specimen TCGA-ZG-A9LM-01A from TCGA case TCGA-ZG-A9LM, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.2 years (26,377 days).
Specimen TCGA-ZG-A9LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.383aa34e-bde9-4afd-9d90-cb33b9dc6e22.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZG-A9LM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 363 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2f206b15-26a2-4664-9e0f-19e4a713f5c3

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 109; copy number 1: 64; copy number 2: 2,426; copy number 3: 14,163; copy number 4: 10,770; copy number 5: 16,828; copy number 6: 9,103; copy number 7: 92; copy number 8: 3,572; copy number 9: 238; copy number 10: 2,895.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZG-A9LM-01A-11D-A41J-01): tumor purity 0.69, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 109 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,492,813–133,596,399, 52 genes (within-gene range 0–3): SMPD4BP, CCDC74A, MED15P4, AC093838.1, POTEKP, RNU6-617P, LINC01087, GRAMD4P8, C2orf27A, AC093838.2, NBEAP2, TOMM40P4, CDRT15P4, CDRT15P3, AC103564.3, AC103564.1, AC103564.2, AJ239322.2, AJ239322.1, LINC01945, AC093787.2, AC093787.1, AC098826.3, AC098826.1, AC098826.2, ANKRD30BL, RNU6-1132P, RNA5-8SP5, MIR663B, CDC27P1, AC097532.1, ZNF806, AC097532.2, AC097532.3, FAM201B, RNU6-175P, GPR39, YBX1P7, RN7SKP103, LYPD1, AC010974.1, NCKAP5, AC010974.2, AC016909.1, NCKAP5-AS1, AC011755.1, NCKAP5-AS2, RNU6-579P, RN7SKP154, NCKAP5-IT1, AC011243.1, RN7SKP93.
- chr5:55,738,017–57,169,209, 38 genes (within-gene range 0–2): DDX4, AC016632.1, RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, AC008391.1, RPL26P19, C5orf67, AC022431.1, AC008940.1, MAP3K1, AC008937.2, AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1, AC114973.1, AC034244.1, AC034244.2, Y_RNA.
- chr8:20,551,201–22,082,527, 19 genes (within-gene range 0–3): AC022559.1, AC018541.1, TMEM97P2, AC015468.3, AC021613.1, AC015468.1, AC015468.2, LINC02153, AC103719.1, AC021613.2, AC021613.3, AC021355.1, GFRA2, OR6R2P, DOK2, XPO7, NPM2, FGF17, DMTN.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
